CCDI case PBBVBJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ce9a77bc-d463-4687-923e-f817c2e3db39

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.9 years (6,187 days).

Biospecimens (3 samples)
- Sample 0DO5DV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO5EU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO5FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
